Somatic mutation profile of tumor specimen TCGA-C5-A1BN-01B (aliquot TCGA-C5-A1BN-01B-11D-A14W-08) from TCGA case TCGA-C5-A1BN, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 26.8 years (9,783 days).
Specimen TCGA-C5-A1BN-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7e075da-199f-428e-8b90-e13f9abedbc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1BN-10A (Blood Derived Normal), aliquot TCGA-C5-A1BN-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8db51f63-2cfa-4be0-ac15-a08875832ced

The open-access MAF lists 76 somatic variants for this specimen: 56 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 17, Nonsense Mutation 6, 3'UTR 2, Frame Shift Ins 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP5 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV54535902; called by muse, mutect2, varscan2
- ACTN1 | c.1885G>T p.E629* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV51990288; called by muse, mutect2, varscan2
- ADRA1A | c.694G>T p.V232L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.163); catalogued as rs757286802, COSV52361466; called by muse, mutect2, varscan2
- ANK3 | c.3451G>A p.G1151S (on ENST00000280772 / NM_001320874.2; = p.G285S on NM_001149.3) | Missense Mutation (SNP) | VAF 50/239 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55047866, COSV55052236; called by muse, mutect2, varscan2
- ATP2A1 | c.2145G>C p.E715D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62869038; called by muse, mutect2
- ATRX | c.1873G>C p.E625Q | Missense Mutation (SNP) | VAF 139/373 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.986); catalogued as COSV64870633, COSV64874563; called by muse, mutect2, varscan2
- ATXN7L2 | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs199993090, COSV100881359, COSV63992132; called by muse, mutect2, varscan2
- BCL9 | c.1974G>A p.M658I | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV52342838; called by muse, mutect2, varscan2
- BCL9 | c.2726dup p.V910Cfs*42 | Frame Shift Ins (INS) | VAF 36/122 reads (30%) | catalogued as rs1553205212; called by mutect2, varscan2
- BCLAF3 | c.2022G>C p.Q674H (on ENST00000379682 / NM_001367774.1; = p.Q645H on NM_198279.3) | Missense Mutation (SNP) | VAF 79/255 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61413649; called by muse, mutect2, varscan2
- BICC1 | c.2302C>T p.P768S | Missense Mutation (SNP) | VAF 126/171 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54063007; called by muse, mutect2, varscan2
- CLCA4 | c.1393C>T p.Q465* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as COSV55367503; called by muse, mutect2, varscan2
- CLEC11A | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs1271110663, COSV51573734; called by muse, mutect2
- COL6A3 | c.2224C>T p.H742Y | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV55085852; called by muse, mutect2, varscan2
- COQ5 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV56018759; called by muse, mutect2, varscan2
- CPA6 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs765895994, COSV52726004; called by muse, mutect2, varscan2
- CYLC1 | c.1614C>G p.I538M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.609); catalogued as COSV100254211, COSV61411303; called by muse, mutect2, varscan2
- CYRIA | c.182A>G p.E61G | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100838564, COSV62864687; called by muse, mutect2
- DAPK1 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.67); catalogued as rs760156331, COSV63786493; called by muse, mutect2, varscan2
- DNAH5 | c.10248C>A p.F3416L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54217267, COSV54226321; called by muse, mutect2, varscan2
- F2RL3 | c.1017C>G p.I339M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV50185377; called by muse, mutect2, varscan2
- GID8 | c.255G>C p.L85F | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV56611299; called by muse, mutect2, varscan2
- GRIK1 | c.1824C>A p.H608Q | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV58714933; called by muse, mutect2, varscan2
- H2AC13 | c.292C>A p.L98M | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.343); catalogued as COSV62440680; called by muse, mutect2, varscan2
- KANSL1 | c.2519C>A p.S840* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV52267150; called by mutect2, varscan2
- LCMT1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66724777; called by muse, mutect2, varscan2
- MARF1 | c.3626C>G p.S1209* | Nonsense Mutation (SNP) | VAF 38/113 reads (34%) | catalogued as COSV60022136; called by muse, mutect2, varscan2
- MGA | c.1529C>T p.T510I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54951786; called by muse, mutect2, varscan2
- MYH8 | c.2805C>G p.I935M | Missense Mutation (SNP) | VAF 124/185 reads (67%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV67963077, COSV67970465; called by muse, mutect2, varscan2
- MYT1L | c.3256A>T p.K1086* | Nonsense Mutation (SNP) | VAF 54/174 reads (31%) | catalogued as COSV67702001; called by muse, mutect2, varscan2
- NELFCD | c.537G>C p.L179F (on ENST00000602795; = p.L161F on NM_198976.4) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59745711; called by muse, mutect2
- NKAPD1 | c.110A>C p.E37A | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54775253; called by muse, mutect2, varscan2
- NPPA | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs150794709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OLFML2A | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs777350219, COSV56582777; called by muse, mutect2, varscan2
- PAF1 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55393328; called by muse, mutect2, varscan2
- POLQ | c.6958C>A p.P2320T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51749448; called by muse, mutect2, varscan2
- PRG4 | c.650C>A p.P217Q | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); catalogued as COSV66623524; called by muse, mutect2, varscan2
- PTH1R | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs773660422, COSV57315072; called by muse, mutect2, varscan2
- PTRH1 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs781266875, COSV58852655; called by muse, mutect2, varscan2
- REPS1 | c.1427-1G>C p.X476_splice | Splice Site (SNP) | VAF 23/69 reads (33%) | catalogued as COSV57809812; called by muse, mutect2, varscan2
- SETD2 | c.3620C>G p.S1207C | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV57435039, COSV57441721; called by muse, mutect2, varscan2
- SPARCL1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 107/173 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV56803035, COSV56803226; called by muse, mutect2, varscan2
- SPARCL1 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV56803045; called by muse, mutect2, varscan2
- SSR3 | c.230A>G p.Y77C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV54020313; called by muse, mutect2, varscan2
- TBC1D5 | c.1376A>G p.N459S | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs1285391609, COSV53753800; called by muse, mutect2, varscan2
- TNIK | c.2512A>C p.S838R | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV52678980; called by muse, mutect2, varscan2
- TUBA3C | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 50/83 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV67139094; called by muse, mutect2, varscan2
- ULK4 | c.3722G>A p.G1241D | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV57204961; called by muse, mutect2, varscan2
- UNK | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.431); catalogued as COSV52883958; called by muse, mutect2, varscan2
- USP26 | c.1106C>A p.S369* | Nonsense Mutation (SNP) | VAF 40/110 reads (36%) | catalogued as COSV63708217, COSV63708421; called by muse, mutect2, varscan2
- ZC2HC1A | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV55667230, COSV55668135; called by muse, mutect2, varscan2
- ZDBF2 | c.4702A>C p.I1568L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV65624154; called by muse, mutect2
- ZNF470 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV57968452; called by muse, mutect2, varscan2
- ZNF566 | c.868A>G p.K290E | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67573550; called by muse, mutect2, varscan2
- ZNF569 | c.1625G>C p.R542T | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV57594519; called by muse, mutect2, varscan2
- ZSCAN18 | c.1153G>A p.V385I | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV53731802, COSV53731992; called by muse, mutect2, varscan2
- DSE | c.1419C>T p.Y473= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs374010235; called by muse, mutect2, varscan2
- INPP5F | c.2646A>T p.V882= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV62820680; called by muse, mutect2, varscan2
- MAGEC2 | c.48C>G p.S16= | Silent (SNP) | VAF 71/176 reads (40%) | catalogued as COSV55998823; called by muse, mutect2, varscan2
- MAGEE1 | c.828C>A p.A276= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV63909571; called by muse, mutect2, varscan2
- MOV10L1 | c.2376G>A p.P792= | Silent (SNP) | VAF 63/188 reads (34%) | catalogued as rs767184868, COSV53169696; called by muse, mutect2, varscan2
- MYNN | c.705C>A p.L235= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV62991132; called by muse, mutect2, varscan2
- NEU2 | c.840C>T p.P280= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV52092409; called by muse, mutect2, varscan2
- OR10C1 | c.327C>T p.G109= (on ENST00000622521; = p.G107= on NM_013941.3) | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as rs1454127751, COSV65822755; called by muse, mutect2, varscan2
- POU2F3 | c.1098C>G p.L366= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as COSV52793234; called by muse, mutect2, varscan2
- PRDM16 | c.687G>A p.T229= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs773103874, COSV54586597; called by muse, mutect2, varscan2
- PWWP3B | c.1741A>C p.R581= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV61799159; called by muse, mutect2, varscan2
- REXO4 | c.678C>T p.S226= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs143883166; called by muse, mutect2, varscan2
- RIMS2 | c.2685T>C p.S895= (on ENST00000666250 / NM_001348490.2; = p.S703= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV51670381; called by muse, mutect2, varscan2
- RYR1 | c.5490C>T p.V1830= | Silent (SNP) | VAF 60/208 reads (29%) | catalogued as rs1243634588, COSV62094279; called by muse, mutect2, varscan2
- SEMA4F | c.1113C>T p.V371= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs1426746439, COSV60282843; called by muse, mutect2, varscan2
- TMOD3 | c.696C>T p.F232= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as COSV100419190; called by muse, mutect2, varscan2
- TRAF4 | c.609C>G p.V203= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV52044244, COSV99261745; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1462G>A | 3'UTR (SNP) | VAF 49/113 reads (43%) | catalogued as COSV57542244; called by muse, mutect2, varscan2
- RANBP1 | chr22:20116426 C>G | 5'Flank (SNP) | VAF 30/73 reads (41%) | catalogued as COSV99350292; called by muse, mutect2, varscan2
- SPAG11B | c.*43T>C | 3'UTR (SNP) | VAF 14/47 reads (30%) | catalogued as rs556400728, COSV52499343; called by muse, mutect2, varscan2
